Gene-level copy-number profile of tumor specimen ALCH-B2MQ-TTP1-B from ALCHEMIST case ALCH-B2MQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.5 years (27,220 days).
Specimen ALCH-B2MQ-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9c382684-f76d-4966-8bf7-6da55d2ce517.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2MQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/fa00209c-de6f-45be-8985-7e23eb279153

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 248; copy number 1: 3,051; copy number 2: 51,434; copy number 3: 3,205; copy number 4: 942; copy number 5: 18; copy number 7: 1; copy number 8: 1; copy number 22: 1; copy number 35: 2; copy number 46: 1.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,232,237–1,235,041, 1 gene: B3GALT6.
- chr1:1,249,777–1,251,334, 1 gene: AL162741.1.
- chr1:1,308,597–1,311,677, 1 gene (within-gene range 0–2): PUSL1.
- chr3:52,495,338–52,524,495, 1 gene (within-gene range 0–2): STAB1.
- chr6:35,070,871–35,071,049, 1 gene (within-gene range 0–2): AL138721.1.
- chr8:141,434,545–141,437,954, 1 gene (within-gene range 0–2): AC100803.4.
- chr8:144,428,775–144,444,440, 3 genes (within-gene range 0–2): TONSL, MIR6893, TONSL-AS1.
- chr11:67,266,473–67,286,556, 1 gene: GRK2.
- chr15:25,189,414–25,208,163, 11 genes (within-gene range 0–2): SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21.
- chr17:16,922,915–16,934,839, 1 gene (within-gene range 0–2): TBC1D27P.
- chr17:21,376,357–21,419,870, 1 gene: KCNJ12.
- chr19:2,425,625–2,427,586, 1 gene (within-gene range 0–2): TIMM13.
- chr19:2,434,914–2,435,000, 1 gene (within-gene range 0–2): MIR7108.
- chr19:48,837,097–48,868,617, 1 gene: PLEKHA4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 24 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:50,396,192–51,275,734, 15 genes, copy number 5: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1.
- chr7:73,861,159–73,865,890, 1 gene, copy number 5: TMEM270.
- chr8:12,178,697–12,182,719, 1 gene, copy number 8 (within-gene range 2–8): ALG1L11P.
- chr14:89,355,060–89,356,571, 1 gene, copy number 7 (within-gene range 2–7): AL357093.1.
- chr19:38,797,002–38,812,945, 2 genes, copy number 5: RNU6-140P, LGALS4.
- chr21:43,053,191–43,107,570, 2 genes, copy number 22–35: CBS, U2AF1.
- chr21:43,115,334–43,115,709, 1 gene, copy number 35: MRPL51P2.
- chr21:43,461,960–43,479,534, 1 gene, copy number 46 (within-gene range 2–46): LINC00313.

Autosomal genes at a single copy (total copy number 1): 439. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
